Somatic mutation profile of tumor specimen 0DY78Q from CCDI case PBCSEE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 4.8 years (1,742 days).
Specimen 0DY78Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23a00535-667c-4045-a607-ed2c654c64b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DY77U (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dab2d123-af48-4755-931d-0d2a5ec158f9

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 124/330 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- GAL3ST1 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 64/264 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1207026980, COSV58892029; called by muse, mutect2, varscan2
- GPR63 | c.848T>A p.I283K | Missense Mutation (SNP) | VAF 69/308 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV100013201; called by muse, mutect2, varscan2
- CPNE5 | c.609C>A p.F203L | Missense Mutation (SNP) | VAF 63/278 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- ITGAX | c.409A>G p.R137G | Missense Mutation (SNP) | VAF 50/319 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.204); called by muse, varscan2
- MAP2K7 | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 32/168 reads (19%) | called by muse, varscan2
- OTOGL | c.6319C>T p.Q2107* (on ENST00000547103; = p.Q2098* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 28/177 reads (16%) | called by muse, mutect2, varscan2
- OTOGL | c.6320A>G p.Q2107R (on ENST00000547103; = p.Q2098R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCAF4 | c.790A>G p.R264G | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, varscan2
- CERS1 | c.114G>C p.T38= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as rs1271581824; called by muse, mutect2, varscan2
- MUC2 | c.2886C>T p.D962= | Silent (SNP) | VAF 53/271 reads (20%) | called by muse, mutect2, varscan2
- TENT4A | c.1098C>T p.F366= | Silent (SNP) | VAF 50/362 reads (14%) | catalogued as COSV100049350; called by muse, mutect2, varscan2
- ZNF783 | c.802+3622C>T | Intron (SNP) | VAF 78/492 reads (16%) | catalogued as rs745929263, COSV65186582; called by muse, varscan2
